Gene-level copy-number profile of tumor specimen TCGA-63-A5MB-01A from TCGA case TCGA-63-A5MB, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5MB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.12abb508-810b-49f0-96ec-2f6d1208cc57.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e3fb319-eaf9-4068-9966-071f92c4f06b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 7,827; copy number 2: 27,332; copy number 3: 13,443; copy number 4: 6,627; copy number 5: 1,703; copy number 6: 846; copy number 7: 528; copy number 8: 927; copy number 9: 313; copy number 10: 103; copy number 11: 62; copy number 14: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MB-01A-11D-A26L-01): tumor purity 0.65, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,826,337, 26 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2.
- chr12:107,374,747–107,374,827, 1 gene: AC009774.1.
- chr18:58,044,226–58,401,540, 1 gene (within-gene range 0–1): NEDD4L.
- chr18:58,371,566–58,372,666, 1 gene: AC090236.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,555 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,127,287–173,363,733, 421 genes, copy number 5–6 (broad region; genes not listed).
- chr1:179,543,201–179,591,305, 5 genes, copy number 5: AL160286.3, NPHS2, RNU5F-2P, AL160286.1, AL160286.2.
- chr1:230,592,660–230,693,982, 3 genes, copy number 6: LINC01737, AL158214.1, COG2.
- chr1:243,005,845–248,919,946, 188 genes, copy number 5 (broad region; genes not listed).
- chr2:44,921,077–46,187,990, 25 genes, copy number 5 (within-gene range 4–5): LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1, KRTCAP2P1, SIX2, AC093702.1, LINC01121, AC093833.1, AC009236.2, AC009236.1, SRBD1, RN7SL414P, PRKCE, PRKCE-AS1, RPL26P15, AC017006.2.
- chr2:54,456,317–56,750,563, 42 genes, copy number 5 (within-gene range 4–5): SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63.
- chr2:57,755,428–59,279,400, 11 genes, copy number 5: ACTG1P22, VRK2, AC068193.1, FANCL, AC007250.1, EIF3FP3, LINC01795, LINC01122, AC007238.1, AC007092.1, LINC01793.
- chr2:59,238,703–59,733,396, 4 genes, copy number 5 (within-gene range 4–5): AC007179.2, AC007179.1, AC007179.3, RNU6-508P.
- chr2:61,710,076–66,200,373, 100 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:76,747,719–77,593,319, 1 gene, copy number 5 (within-gene range 4–5): LRRTM4.
- chr2:76,985,965–77,327,103, 2 genes, copy number 5: LRRTM4-AS1, AC013716.1.
- chr2:94,725,674–128,067,901, 648 genes, copy number 5–10 (broad region; genes not listed).
- chr3:148,279,682–198,222,513, 898 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr4:6,575,189–19,098,740, 226 genes, copy number 5–9 (broad region; genes not listed).
- chr4:19,181,814–19,181,856, 1 gene, copy number 5: RNA5SP157.
- chr4:46,993,723–49,589,529, 52 genes, copy number 5 (within-gene range 3–5): GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:58,198–956,520, 36 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1.
- chr5:12,297,399–37,753,435, 340 genes, copy number 5–9 (broad region; genes not listed).
- chr5:45,254,948–45,895,970, 4 genes, copy number 5 (within-gene range 2–5): HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:38,481,692–62,611,327, 404 genes, copy number 7–14 (broad region; genes not listed).
- chr6:169,369,998–170,738,536, 38 genes, copy number 6: LINC02519, AL009176.1, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL603783.1, AL596442.4, AL596442.3, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL031259.1, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr8:123,002,560–123,416,350, 23 genes, copy number 5: AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6.
- chr12:20,810,702–34,249,958, 260 genes, copy number 5–10 (broad region; genes not listed).
- chr12:47,377,638–52,736,142, 255 genes, copy number 5 (broad region; genes not listed).
- chr12:59,596,029–76,880,352, 303 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:6,873,899–7,004,112, 2 genes, copy number 6: RNU6-457P, RNU6-328P.
- chr17:26,981,694–31,382,116, 240 genes, copy number 6 (broad region; genes not listed).
- chr20:39,329,014–40,854,229, 12 genes, copy number 5: ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484.
- chr21:45,974,489–46,184,476, 11 genes, copy number 5 (within-gene range 2–5): AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L.

Autosomal genes at a single copy (total copy number 1): 7,827. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
